Somatic mutation profile of tumor specimen 0DUXOX from CCDI case PBBYIM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 3.9 years (1,440 days).
Specimen 0DUXOX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1d93b61-61ba-43fd-8f74-53fb3e3b82f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/459c3cc3-1e1e-4b68-b1ad-a9c3b04b26e7

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'UTR 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HARS1 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 436/758 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1210579780; called by muse, mutect2, varscan2
- OR4K15 | c.178C>A p.L60I (on ENST00000305051; = p.L36I on NM_001005486.1) | Missense Mutation (SNP) | VAF 40/613 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1373392170; called by muse, mutect2
- POSTN | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 94/2058 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.751); catalogued as rs117790304; called by muse, mutect2
- STAT5B | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 526/1172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1270912751; called by muse, mutect2, varscan2
- TAMM41 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 52/840 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.039); catalogued as rs374882230; called by muse, mutect2
- ZNF536 | c.3842G>A p.G1281E | Missense Mutation (SNP) | VAF 47/828 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1568545002; called by muse, mutect2
- ELF1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 58/800 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2
- HSPA4L | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 36/1160 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2
- KDM6B | c.693A>G p.R231= | Silent (SNP) | VAF 288/959 reads (30%) | called by muse, mutect2, varscan2
- PLXNB3 | c.3675C>T p.F1225= | Silent (SNP) | VAF 449/513 reads (88%) | catalogued as rs376208061, COSV62801870; called by muse, mutect2, varscan2
- HTN1 | c.*10T>C | 3'UTR (SNP) | VAF 654/1004 reads (65%) | called by muse, mutect2
- LACC1 | c.*180T>C | 3'UTR (SNP) | VAF 200/548 reads (36%) | called by muse, mutect2, varscan2
- TEX30 | c.505-52_505-49del | Intron (DEL) | VAF 36/199 reads (18%) | called by mutect2, pindel, varscan2
